Somatic mutation profile of tumor specimen TARGET-20-PATJWN-04A (aliquot TARGET-20-PATJWN-04A-01D) from TARGET case TARGET-20-PATJWN, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.2 years (1,539 days).
Specimen TARGET-20-PATJWN-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c3158c3b-0f08-4912-99e7-935e859c5bfc.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PATJWN-14A (Bone Marrow Normal), aliquot TARGET-20-PATJWN-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e0ba762-b847-43dd-8d84-63a80765f245

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Splice Site 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH2 | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 51/133 reads (38%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs267606870, CM106819, COSV57469615, COSV57472768; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 20/52 reads (38%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, varscan2
- SETD2 | c.4715+1G>A p.X1572_splice | Splice Site (SNP) | VAF 63/155 reads (41%) | hotspot (GDC flag); catalogued as COSV57431126, COSV57439397; called by muse, varscan2
- NCOR1 | c.5944_5957del p.P1982Gfs*12 | Frame Shift Del (DEL) | VAF 42/171 reads (25%) | called by mutect2, pindel, varscan2
- SETD2 | c.4670C>A p.T1557K | Missense Mutation (SNP) | VAF 82/198 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.355); called by muse, varscan2
